Somatic mutation profile of tumor specimen TCGA-78-8655-01A (aliquot TCGA-78-8655-01A-11D-2393-08) from TCGA case TCGA-78-8655, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 77.7 years (28,379 days).
Specimen TCGA-78-8655-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8285c1d-f550-402b-9280-7e3ca9c9db03.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-78-8655-10A (Blood Derived Normal), aliquot TCGA-78-8655-10A-01D-2393-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8c70d6b-6eea-40aa-8125-ff5186e8706f

The open-access MAF lists 113 somatic variants for this specimen: 91 protein-altering or splice-affecting, 20 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 75, Silent 20, Nonsense Mutation 8, Frame Shift Del 5, In Frame Del 2, Splice Region 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 10/14 reads (71%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- ABCG4 | c.891G>T p.L297F | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as rs1565815160, COSV100266412; called by muse, mutect2, varscan2
- ADAMTS12 | c.2839G>T p.D947Y | Missense Mutation (SNP) | VAF 41/233 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs967595882, COSV100710098; called by muse, mutect2, varscan2
- AFF2 | c.3365C>A p.S1122Y | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54001888; called by muse, mutect2, varscan2
- AFP | c.1583A>T p.D528V | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as rs777205441, COSV99889596; called by muse, mutect2, varscan2
- ALKBH1 | c.862G>T p.A288S | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99380401; called by muse, mutect2
- ANKMY1 | c.1576C>T p.R526C | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV56041523; called by muse, mutect2, varscan2
- APBA2 | c.946G>T p.E316* | Nonsense Mutation (SNP) | VAF 6/17 reads (35%) | catalogued as COSV101381803, COSV68792774, COSV68795881; called by muse, mutect2
- ASPH | c.190C>G p.L64V | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100727321; called by muse, mutect2, varscan2
- BCORL1 | c.2475C>A p.S825R | Missense Mutation (SNP) | VAF 31/159 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV99498206; called by muse, mutect2, varscan2
- C14orf178 | n.296A>G | Splice Region (SNP) | VAF 43/170 reads (25%) | catalogued as COSV100575623; called by muse, mutect2, varscan2
- CCSER1 | c.749A>G p.D250G | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100387141; called by muse, mutect2, varscan2
- CDH10 | c.983del p.G328Afs*5 | Frame Shift Del (DEL) | VAF 38/204 reads (19%) | catalogued as COSV100050899; called by mutect2, pindel*, varscan2
- CLEC4C | c.416_418del p.S139del | In Frame Del (DEL) | VAF 41/88 reads (47%) | catalogued as rs778835178; called by pindel, varscan2
- CSMD1 | c.5661C>A p.N1887K (on ENST00000520002; = p.N1886K on NM_033225.6) | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100142046; called by muse, mutect2, varscan2
- CSNK1G2 | c.1221G>C p.K407N | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.821); catalogued as rs757671967, COSV99729491; called by muse, mutect2, varscan2
- DHRS7C | c.322C>T p.P108S (on ENST00000330255 / NM_001220493.2; = p.P107S on NM_001105571.3) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.68); PolyPhen benign (0.014); catalogued as COSV100364506, COSV57649575; called by muse, mutect2, varscan2
- EPHA3 | c.2387T>C p.I796T | Missense Mutation (SNP) | VAF 53/163 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60706263, COSV60727761; called by muse, mutect2, varscan2
- FAM47A | c.1201C>A p.P401T | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV100649664; called by muse, mutect2, varscan2
- FXYD5 | c.10T>G p.S4A | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV99544683; called by muse, mutect2, varscan2
- GBP3 | c.551C>T p.S184F | Missense Mutation (SNP) | VAF 88/191 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.03); catalogued as rs776107022, COSV99352290; called by muse, mutect2, varscan2
- GNGT1 | c.128A>G p.Y43C | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99949718; called by muse, mutect2
- GNGT1 | c.130G>T p.V44F | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.209); catalogued as COSV99949721; called by muse, mutect2
- GOLPH3 | c.620A>T p.N207I | Missense Mutation (SNP) | VAF 46/182 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.18); catalogued as COSV99416919; called by muse, mutect2, varscan2
- HADHB | c.1087C>G p.L363V | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100501772; called by muse, mutect2, varscan2
- HAND1 | c.243C>G p.S81R | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0.122); catalogued as COSV99163941; called by muse, mutect2, varscan2
- HAND1 | c.242G>A p.S81N | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.062); catalogued as COSV50562450; called by muse, varscan2
- HAUS7 | c.676G>T p.A226S | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.117); catalogued as COSV100443920; called by muse, mutect2, varscan2
- HCN1 | c.2641G>A p.A881T | Missense Mutation (SNP) | VAF 24/235 reads (10%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as rs56377228, CM080409, COSV57525330; called by muse, mutect2, varscan2
- IL13RA1 | c.469A>G p.N157D | Missense Mutation (SNP) | VAF 48/258 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV100861675; called by muse, mutect2, varscan2
- KIF1C | c.3085C>T p.P1029S | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.026); catalogued as COSV100296903; called by muse, mutect2, varscan2
- LARGE1 | c.1622A>T p.Y541F | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.861); catalogued as COSV100504320; called by muse, mutect2, varscan2
- LRATD1 | c.31C>A p.L11I | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV99706923; called by muse, mutect2, varscan2
- MATR3 | c.697G>T p.D233Y | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.226); catalogued as COSV100735078; called by muse, mutect2, varscan2
- MN1 | c.2783C>T p.S928L | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.414); catalogued as rs746306235, COSV100179606; called by muse, mutect2, varscan2
- MYH13 | c.5108G>A p.R1703H | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142532419; called by muse, mutect2, varscan2
- MYO7A | c.861A>G p.I287M | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.151); catalogued as COSV101289007; called by muse, mutect2
- NCKAP5 | c.889C>T p.R297* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as rs781035021, COSV58432051; called by mutect2, varscan2
- NLGN3 | c.277T>A p.W93R | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100704497; called by muse, mutect2, varscan2
- NMUR2 | c.980A>G p.Y327C | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99676513; called by muse, mutect2, varscan2
- NOLC1 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.34); catalogued as rs192399476, COSV64180642; called by muse, mutect2, varscan2
- NRF1 | c.1318G>T p.G440* | Nonsense Mutation (SNP) | VAF 41/89 reads (46%) | catalogued as COSV56217093; called by muse, mutect2, varscan2
- NRXN1 | c.3443G>T p.R1148L | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100452654, COSV58460250; called by muse, mutect2, varscan2
- OGDHL | c.1581C>A p.Y527* | Nonsense Mutation (SNP) | VAF 13/45 reads (29%) | catalogued as COSV100934151, COSV65104940; called by muse, mutect2, varscan2
- OR10G8 | c.542C>A p.P181Q | Missense Mutation (SNP) | VAF 66/226 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV101461769, COSV70909383; called by muse, mutect2, varscan2
- OR4K14 | c.96T>G p.F32L | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100520320; called by muse, mutect2, varscan2
- OR51T1 | c.925C>T p.L309F | Missense Mutation (SNP) | VAF 64/137 reads (47%) | SIFT tolerated (0.58); PolyPhen benign (0.011); catalogued as COSV100434251; called by muse, mutect2, varscan2
- OTOGL | c.5983C>T p.R1995* (on ENST00000547103; = p.R1986* on NM_173591.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 35/49 reads (71%) | catalogued as rs779580098, COSV54020830; called by muse, mutect2, varscan2
- PARVG | c.10G>T p.E4* | Nonsense Mutation (SNP) | VAF 8/33 reads (24%) | catalogued as COSV100796019; called by muse, mutect2, varscan2
- PASD1 | c.1431C>G p.F477L | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100948993; called by muse, mutect2
- PAX3 | c.1306A>G p.M436V | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.01); catalogued as rs944943242, COSV100398883; called by muse, mutect2, varscan2
- PCDH11X | c.2162G>T p.R721I | Missense Mutation (SNP) | VAF 50/155 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.812); catalogued as COSV100007139; called by muse, mutect2, varscan2
- PCDH8 | c.2857G>T p.A953S | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.76); PolyPhen benign (0.056); catalogued as COSV100131084, COSV100131636; called by muse, mutect2
- PCDHGA12 | c.775A>G p.T259A | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.597); catalogued as rs1331176313, COSV52745833; called by muse, mutect2, varscan2
- PDGFRA | c.2879A>T p.K960M | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV99955218; called by muse, mutect2, varscan2
- PITPNM3 | c.2431G>T p.G811W | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99337800, COSV99337991; called by muse, mutect2, varscan2
- PPP1R3F | c.1568G>T p.S523I | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.125); catalogued as COSV99278287; called by muse, mutect2, varscan2
- RASGEF1A | c.1269G>A p.W423* | Nonsense Mutation (SNP) | VAF 29/61 reads (48%) | catalogued as COSV100988616; called by muse, mutect2, varscan2
- RP1 | c.1283C>A p.A428D | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.053); catalogued as COSV55109978, COSV99605844; called by muse, mutect2, varscan2
- RP1L1 | c.5073G>T p.Q1691H | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.025); catalogued as COSV101222849; called by muse, mutect2, varscan2
- RYR1 | c.11315G>T p.R3772L | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as CM073325, COSV100614110; called by muse, mutect2, varscan2
- RYR2 | c.3691G>T p.G1231C | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as COSV100767212; called by muse, mutect2, varscan2
- SENP7 | c.1423A>T p.T475S | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0.053); catalogued as COSV100052103; called by muse, mutect2, varscan2
- SGO1 | c.393A>T p.R131S | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV99768060; called by muse, mutect2, varscan2
- SIAH3 | c.583C>T p.Q195* | Nonsense Mutation (SNP) | VAF 10/32 reads (31%) | catalogued as COSV101247635; called by muse, mutect2, varscan2
- SLC17A1 | c.732G>T p.Q244H | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.261); catalogued as COSV99765497; called by muse, mutect2, varscan2
- SLC4A1 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs749020872, COSV99292909; called by muse, mutect2, varscan2
- SMURF1 | c.1996G>A p.V666M | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); catalogued as COSV100705336; called by muse, mutect2, varscan2
- SNRNP200 | c.4564C>T p.P1522S | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.403); catalogued as COSV60494770; called by muse, mutect2, varscan2
- SPATC1L | c.866C>G p.P289R (on ENST00000291672 / NM_001142854.2; = p.P135R on NM_032261.5) | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as COSV99385767; called by muse, mutect2, varscan2
- ST8SIA6 | c.465G>T p.E155D | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as COSV66468223; called by muse, mutect2, varscan2
- TAF1B | c.319A>G p.N107D | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.417); catalogued as rs889054404, COSV99721738; called by muse, mutect2, varscan2
- THSD7A | c.4790C>A p.P1597Q | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV68472071; called by muse, mutect2, varscan2
- TMPRSS15 | c.645C>A p.D215E | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776663117, COSV53034121, COSV53037710; called by muse, mutect2, varscan2
- TOB1 | c.724C>G p.Q242E | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV99278699; called by mutect2, varscan2
- TRIML2 | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.779); catalogued as COSV100455810; called by muse, mutect2, varscan2
- TULP4 | c.3394G>T p.V1132F | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV100893014; called by muse, mutect2, varscan2
- TXNDC16 | c.308A>G p.Y103C | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1309498461, COSV99908673; called by muse, mutect2
- UGT2A3 | c.205C>A p.P69T | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.173); catalogued as COSV99279489; called by muse, mutect2, varscan2
- VCAN | c.1835C>A p.P612H | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as COSV99424305; called by muse, mutect2, varscan2
- WWC3 | c.2332G>A p.E778K | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.526); catalogued as COSV101080910; called by muse, mutect2
- ZNF157 | c.1077G>T p.Q359H | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV100998421; called by muse, mutect2, varscan2
- ZNF613 | c.1366T>G p.F456V (on ENST00000293471 / NM_001031721.4; = p.F420V on NM_024840.4) | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as COSV99522812; called by muse, mutect2, varscan2
- ZPBP | c.634C>A p.L212I | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT tolerated (0.82); PolyPhen benign (0.011); catalogued as COSV99248747; called by muse, mutect2, varscan2
- ARHGAP36 | c.1399del p.E467Kfs*123 | Frame Shift Del (DEL) | VAF 19/148 reads (13%) | called by mutect2, pindel, varscan2
- BMP2K | c.1633_1636del p.F545Nfs*5 | Frame Shift Del (DEL) | VAF 17/54 reads (31%) | called by pindel, varscan2
- C5 | c.2940del p.G981Dfs*4 | Frame Shift Del (DEL) | VAF 28/94 reads (30%) | called by mutect2, pindel, varscan2
- COPA | c.3291_3293del p.Q1097_P1098delinsH | In Frame Del (DEL) | VAF 16/57 reads (28%) | called by pindel, varscan2
- COPA | c.3285C>A p.N1095K | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, varscan2
- IGHV3OR16-8 | c.113G>C p.R38T | Missense Mutation (SNP) | VAF 61/229 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.581); called by muse, mutect2, varscan2
- OTOGL | c.5427del p.K1810Rfs*16 (on ENST00000547103; = p.K1801Rfs*16 on NM_173591.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 10/12 reads (83%) | called by mutect2, varscan2
- ABCG8 | c.1893T>C p.S631= | Silent (SNP) | VAF 30/108 reads (28%) | catalogued as COSV99699360; called by muse, mutect2, varscan2
- ARHGDIA | c.87C>T p.P29= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as COSV99482439; called by muse, mutect2, varscan2
- ASPN | c.699C>A p.T233= | Silent (SNP) | VAF 35/118 reads (30%) | catalogued as COSV100978534; called by muse, mutect2, varscan2
- ATP1B4 | c.954C>T p.D318= (on ENST00000218008 / NM_001142447.3; = p.D314= on NM_012069.5) | Silent (SNP) | VAF 26/171 reads (15%) | catalogued as rs753848544, COSV54315956; called by muse, mutect2, varscan2
- BEND2 | c.2399G>A p.*800= | Silent (SNP) | VAF 25/152 reads (16%) | catalogued as COSV66221297; called by muse, mutect2, varscan2
- CARMIL1 | c.1986A>T p.L662= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as COSV100276614; called by muse, mutect2
- CUL7 | c.882G>A p.L294= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as COSV99537604; called by muse, mutect2, varscan2
- FLT1 | c.2598G>A p.G866= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs1566289108, COSV99146873; called by muse, mutect2, varscan2
- KLF17 | c.615C>A p.L205= | Silent (SNP) | VAF 27/106 reads (25%) | catalogued as COSV100954771; called by muse, mutect2, varscan2
- MAP1B | c.1659T>C p.P553= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as COSV57108945; called by muse, mutect2, varscan2
- MRGPRE | c.309C>T p.R103= | Silent (SNP) | VAF 17/92 reads (18%) | catalogued as COSV101099958; called by muse, mutect2, varscan2
- NCAM1 | c.327C>G p.T109= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as COSV100376724, COSV100376819; called by muse, mutect2, varscan2
- NCAM1 | c.672C>T p.T224= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as rs782323015, COSV57516895; called by muse, mutect2, varscan2
- OR5F1 | c.417C>A p.T139= | Silent (SNP) | VAF 25/86 reads (29%) | catalogued as rs201523946, COSV53546357, COSV99558312; called by muse, mutect2, varscan2
- PPP1R1B | c.201G>A p.K67= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as rs966210754, COSV99566075; called by muse, mutect2, varscan2
- PTCHD1 | c.2490A>T p.I830= | Silent (SNP) | VAF 27/110 reads (25%) | catalogued as COSV101037125; called by muse, mutect2, varscan2
- RAMAC | c.342T>G p.P114= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as COSV100417837; called by muse, mutect2, varscan2
- RNF113A | c.294G>T p.V98= | Silent (SNP) | VAF 72/474 reads (15%) | catalogued as COSV101006934; called by muse, mutect2, varscan2
- SPHK1 | c.969C>T p.P323= (on ENST00000392496 / NM_001355139.2; = p.P337= on NM_021972.4) | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as rs775121689, COSV100039100; called by muse, mutect2, varscan2
- XPO6 | c.1893C>T p.Y631= | Silent (SNP) | VAF 29/92 reads (32%) | catalogued as rs773071423, COSV100484605; called by muse, mutect2, varscan2
- CFAP47 | c.5536-647G>T | Intron (SNP) | VAF 13/71 reads (18%) | catalogued as COSV100544787; called by muse, mutect2, varscan2
- HERC2P3 | n.2150del | RNA (DEL) | VAF 14/85 reads (16%) | called by mutect2, pindel, varscan2
